Somatic mutation profile of tumor specimen 0DRXEJ from CCDI case PBCHCZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,218 days).
Specimen 0DRXEJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 003138c7-769b-49cf-b1a3-e455fd0d486f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY8A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38f9f7c5-22ea-4fa7-bd47-f6a433b59d9b

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 3, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83B | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 90/790 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410767041, COSV60921083; called by muse, mutect2
- FAT3 | c.12004C>T p.R4002C | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53109982; called by muse, mutect2
- MAGEC1 | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 123/502 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1324411329, COSV53570176, COSV99597043; called by muse, mutect2, varscan2
- THADA | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 42/800 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375558518; called by muse, mutect2
- DHRS7B | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 96/1235 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FSCB | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 100/831 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KIF1B | c.2118C>T p.D706= (on ENST00000377086 / NM_001365952.1; = p.D660= on NM_015074.3) | Splice Region (SNP) | VAF 80/633 reads (13%) | called by muse, mutect2, varscan2
- MROH2A | c.3971G>T p.G1324V | Missense Mutation (SNP) | VAF 59/462 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MTUS2 | c.245A>C p.Q82P | Missense Mutation (SNP) | VAF 92/918 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- MYH11 | c.3232A>T p.I1078F | Missense Mutation (SNP) | VAF 78/694 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- USP12 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 249/1271 reads (20%) | called by muse, mutect2, varscan2
- FAM20B | c.1053G>A p.K351= | Silent (SNP) | VAF 67/808 reads (8%) | catalogued as rs1264847434; called by muse, mutect2
- IGF2R | c.3942G>A p.T1314= | Silent (SNP) | VAF 218/968 reads (23%) | catalogued as rs371109078; called by mutect2, varscan2
- MUC16 | c.43188G>A p.S14396= | Silent (SNP) | VAF 232/544 reads (43%) | catalogued as rs762197996, COSV66690291; called by muse, mutect2, varscan2
- ABCB6 | c.1386+98T>C | Intron (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2
- PTGER3 | c.1077+61T>C | Intron (SNP) | VAF 70/539 reads (13%) | called by muse, varscan2
- TK2 | c.64-4925G>A | Intron (SNP) | VAF 61/584 reads (10%) | called by muse, mutect2, varscan2
